Somatic mutation profile of tumor specimen C3L-04971-61 (aliquot CPT0339330002) from CPTAC case C3L-04971, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 42.1 years (15,380 days).
Specimen C3L-04971-61: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8366637-910d-4fbd-8de0-2839dab29923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04971-50 (Buccal Cell Normal), aliquot CPT0343350004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d72febb-6a35-4e27-8ba1-2dd80bd06778

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 5'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 216/601 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533755775, COSV99699246; called by muse, mutect2, varscan2
- ARHGAP31 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 198/645 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749283093; called by muse, mutect2, varscan2
- CDR2 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370795647; called by muse, mutect2, varscan2
- DSG4 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs865865878; called by muse, mutect2, varscan2
- KCNC2 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); catalogued as COSV54361888; called by muse, mutect2, varscan2
- MYH14 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs766802012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA3 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 166/209 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782380731; called by muse, mutect2, varscan2
- SEMA5A | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs752770800, COSV66791233; called by muse, mutect2, varscan2
- TNFAIP1 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs1555578279; called by muse, mutect2, varscan2
- DDX51 | c.1350del p.L451Ffs*6 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | called by mutect2, pindel, varscan2
- C19orf38 | c.57C>T p.S19= | Silent (SNP) | VAF 83/277 reads (30%) | called by muse, mutect2, varscan2
- FAM184B | c.273C>T p.C91= | Silent (SNP) | VAF 134/361 reads (37%) | catalogued as COSV53951569; called by muse, mutect2, varscan2
- TMEM62 | c.1098T>A p.V366= | Silent (SNP) | VAF 52/148 reads (35%) | called by muse, mutect2, varscan2
- C2CD5 | c.2534-1413G>C | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SGK1 | chr6:134175566 C>T | 5'Flank (SNP) | VAF 126/286 reads (44%) | catalogued as COSV52814565; called by muse, varscan2
